Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6625, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6625-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. SIGMOID COLON
- B. PROXIMAL DONUT
- C. DISTAL DONUT

DIAGNOSIS:

- A. SIGMOID COLON, SEGMENTAL RESECTION:
INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA EXTENDING TO SUBSerosa
-TUMOR SIZE: 3.5x3.2x0.6 CM
-ANGIOLYMPHATIC/PERINEURAL INVASION NOT IDENTIFIED.
-EIGHTEEN LYMPH NODES NEGATIVE FOR TUMOR (0/18)
-TUMOR ARISES IN TUBULAR ADENOMA
-UNINVOLVED COLON SHOWS: HYPERPLASTIC POLYP AND DIVERTICULUM
- SEE TEMPLATE
- B. COLON, PROXIMAL DONUT, EXCISION:
COLONIC TISSUE, NO TUMOR SEEN.
- C. COLON, DISTAL DONUT, EXCISION:
COLONIC TISSUE, NO TUMOR SEEN.

COLORECTAL CANCER TEMPLATE

Tumor Size (cm): 3.5x3.2x0.6 cm
Histologic Type: adenocarcinoma
Grade/Differentiation: moderate
Invasion Depth: subserosa
Invasion Vasc/Lymphatic: absent
Invasion Perineural: absent
Extension to Adj. Areas: no
Margins: free
Lymph Nodes: negative (0/18)
Stage Pathology: T3 N0 Mx
Precursor: present, tubular adenoma
Non-neoplastic areas: hyperplastic polyp, diverticulum

SPECIMEN(S):

- A. SIGMOID COLON B. PROXIMAL DONUT C. DISTAL DONUT

CLINICAL HISTORY:

None

GROSS DESCRIPTION:

- A. SIGMOID COLON
Received fresh is a 20.0cm. segment of colon with both margins received stapled closed measuring 4.5cm. in diameter and 5.0cm. in diameter. The attached portion of pericolic fat measures 20.0x6.5x2.5cm. Upon opening, the mucosa shows a 3.5x3.2x0.6cm. pink tan ulcerated exophytic polypoid mass located 6.8cm. from the wide margin and 11.0cm. from the narrower margin. Remaining colonic mucosa is pink tan and smooth with a single diverticulum located 2.5cm. from the narrow margin. The tumor is noted to extend into the fat but not to the peritoneal surface. The radial margin of resection is free of any lesion. The peritoneal surface of the tumor and the margins are marked by black ink. No discrete nodule lesion is identified in the pericolic fat. Multiple small lymph nodes are identified ranging in size from < 0.1cm to 1.0cm. Representative tissue is submitted in nineteen cassettes as follows:
- A1: 4.5cm. shaved margin
- A2: 5.0cm. shaved margin
- A3: mass with deep margin
- A4: mass
- A5: mass with lymph nodes and fatty tissue

[page 2 of 2]
A6: one lymph node and deep fatty tissue contiguous with A5

A7-A8: mass

A9: diverticulum

A10: radial margin

A11: uninvolved colonic mucosa

A12: five peritumoral lymph nodes

A13: four peritumoral lymph nodes

A14: two possible peritumoral lymph nodes

A15: two possible peritumoral lymph nodes

A16: five lymph nodes at narrow margin

A17: four possible lymph nodes at narrow margin

A18: two lymph nodes at wide margin

A19: one lymph node bisected at wide margin

B. PROXIMAL DONUT

Received without fixative is a ring shaped 1.5x1.5x0.7cm. fragment of smooth, stapled colonic mucosa with slight, focal pink red discoloration. The stapled part is removed and representative tissue is submitted in one cassette.

C. DISTAL DONUT

Received without fixative is a 1.5x1.5x1.0cm. ring shaped fragment of colonic mucosa with multiple staples. The mucosa is tan, smooth with no discrete lesion. The stapled part is removed and the remaining fragment of tissue is submitted in one cassette.

Source: NCI Genomic Data Commons file 9adbbcb5-e4dd-4ef0-bf97-27fd0ac4b527 (TCGA-G4-6625.02B591AB-281B-45C1-A036-925CDC6CEF73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).